Somatic mutation profile of tumor specimen ALCH-B2NP-TTP1-A (aliquot ALCH-B2NP-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2NP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen ALCH-B2NP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61747de6-b25a-4d75-8738-7a82ea76226e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2NP-NB1-A (Blood Derived Normal), aliquot ALCH-B2NP-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da9eeaf6-dfeb-4eff-9f56-c698412f917b

The open-access MAF lists 184 somatic variants for this specimen: 132 protein-altering or splice-affecting, 30 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 30, Intron 13, Nonsense Mutation 7, Splice Site 5, 5'UTR 3, 5'Flank 3, Splice Region 2, RNA 1, 3'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 42/303 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2
- ANKS1B | c.3392del p.R1131Lfs*23 (on ENST00000547776 / NM_152788.4; = p.R297Lfs*23 on NM_020140.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as COSV59115201; called by mutect2, varscan2
- ATXN1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1394208682; called by muse, mutect2
- CCDC168 | c.20434C>G p.L6812V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as COSV59421707; called by muse, mutect2
- CDC73 | c.934A>G p.M312V | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs1425016725; called by muse, mutect2
- CMPK2 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749028346; called by muse, mutect2, varscan2
- CNOT2 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV57506340; called by muse, mutect2, varscan2
- CSMD2 | c.5198C>G p.T1733R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53915039; called by muse, mutect2, varscan2
- CSMD3 | c.9895C>G p.Q3299E (on ENST00000297405 / NM_001363185.1; = p.Q3130E on NM_052900.3) | Missense Mutation (SNP) | VAF 34/525 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.08); catalogued as COSV52213913; called by muse, mutect2
- CSMD3 | c.9187G>T p.G3063C (on ENST00000297405 / NM_001363185.1; = p.G2894C on NM_052900.3) | Missense Mutation (SNP) | VAF 38/508 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99848057; called by muse, mutect2
- DSG4 | c.1889C>A p.P630Q | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1186369817; called by muse, mutect2
- ELK1 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV55952386; called by muse, mutect2
- EPHB6 | c.2404G>T p.V802L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63891117; called by muse, mutect2, varscan2
- FANCI | c.3925-3T>C | Splice Region (SNP) | VAF 26/314 reads (8%) | catalogued as rs1335704587; called by muse, mutect2
- FASTKD5 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs773198969; called by muse, mutect2, varscan2
- GOLGA5 | c.1418A>G p.H473R | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs961101058; called by muse, mutect2
- GPR149 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV101078268; called by muse, mutect2
- GRIK1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs375169701; called by muse, mutect2
- ITGA4 | c.2069A>T p.E690V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV67896668; called by muse, mutect2
- ITGA8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs748005596, COSV65229891; called by muse, mutect2, varscan2
- KYNU | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51581663; called by muse, mutect2
- LSM14B | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs571955948; called by muse, mutect2
- MTHFS | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394587998; called by muse, mutect2
- MYH1 | c.5011C>A p.L1671M | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV99874711; called by muse, mutect2
- NFATC2 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 24/204 reads (12%) | catalogued as COSV65357497; called by muse, mutect2, varscan2
- NRK | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1186898738; called by muse, mutect2, varscan2
- OR4N2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100269369; called by muse, mutect2
- OR6Y1 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755891716; called by muse, mutect2, varscan2
- PDE6C | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs199926911, COSV65116517; called by muse, mutect2
- PIK3CB | c.1530+1del p.X510_splice | Splice Site (DEL) | VAF 14/168 reads (8%) | catalogued as COSV100005803, COSV56684580; called by mutect2, pindel
- PRDM9 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57008655; called by muse, mutect2, varscan2
- RAB1B | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1425247447; called by muse, mutect2
- RFX6 | c.457T>A p.C153S | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100263883; called by muse, mutect2
- SCAF4 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs775068471; called by muse, mutect2
- SEPTIN8 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs759485146; called by muse, mutect2
- SNAP91 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV52117490; called by muse, mutect2
- SPTA1 | c.5092G>T p.V1698F | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100934324, COSV63750962; called by muse, mutect2
- SSH1 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV58459490; called by muse, mutect2
- TG | c.7513G>T p.D2505Y | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55064395; called by muse, mutect2
- THSD7A | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs370197184; called by mutect2, varscan2
- TIMM23 | c.106+1G>T p.X36_splice | Splice Site (SNP) | VAF 16/196 reads (8%) | catalogued as rs782431897; called by muse, mutect2
- TLR4 | c.2191C>T p.R731* (on ENST00000355622 / NM_138554.5; = p.R691* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as rs201670644, COSV62924047; called by muse, mutect2
- TP53 | c.1044G>T p.L348F | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52730754, COSV52829880; called by muse, mutect2
- TPR | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.081); catalogued as rs921709594, COSV66601105, COSV66604714; called by muse, mutect2, varscan2
- TRIM77 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as COSV68066103, COSV68067100; called by muse, mutect2
- TTN | c.20213G>T p.G6738V (on ENST00000591111; = p.G5811V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | PolyPhen possibly damaging (0.822); catalogued as rs1189873191, COSV60035171; called by muse, mutect2
- UGT1A4 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs72551336; called by muse, mutect2
- ZFHX4 | c.7809C>A p.H2603Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.245); catalogued as COSV50671700; called by muse, mutect2, varscan2
- ZKSCAN8 | c.172C>A p.R58S | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs755669536; called by muse, mutect2
- ZSCAN20 | c.1803G>T p.E601D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV100792531; called by muse, mutect2, varscan2
- ABCC2 | c.4526A>T p.N1509I | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- ADGRA3 | c.1682A>T p.Q561L | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- ADGRL3 | c.4152C>A p.N1384K (on ENST00000506720 / NM_001322402.2; = p.N1273K on NM_015236.6) | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.034); called by muse, mutect2
- ANKIB1 | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APOA4 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- ARHGEF6 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ARID5A | c.453C>G p.D151E | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ATXN3L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- BCOR | c.1703C>G p.A568G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- BRWD3 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 49/534 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC22 | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- CCP110 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CEMIP | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 18/433 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); called by muse, mutect2
- CEP170 | c.4177G>T p.E1393* | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | called by muse, varscan2
- CMAS | c.1061T>C p.V354A | Missense Mutation (SNP) | VAF 54/463 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNBD1 | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNGB3 | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- COL4A1 | c.3724G>T p.G1242C | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD2 | c.9578C>T p.P3193L | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTAGE9 | c.173T>C p.F58S | Missense Mutation (SNP) | VAF 40/969 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CTNND2 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.10515G>A p.V3505= | Splice Region (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- DNAH8 | c.7066T>C p.W2356R | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPYD | c.2182G>C p.G728R | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- DSC2 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 37/410 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- EFR3A | c.1565T>A p.F522Y | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA3 | c.1987C>A p.Q663K | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EPHA5 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FAT1 | c.2606C>G p.S869* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- FGF13 | c.176G>T p.R59I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.434); called by muse, mutect2
- HACE1 | c.2696T>A p.L899Q | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HCFC1 | c.4712T>C p.V1571A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNK5 | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIAA1210 | c.4354G>T p.D1452Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- KIF3B | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB4 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2
- LRRC32 | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYZL2 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.118); called by muse, mutect2
- MAGEB18 | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEE2 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.291); called by muse, mutect2
- MOGAT2 | c.908A>T p.Q303L | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2
- MTF2 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MUC17 | c.9683C>A p.P3228H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYCBP2 | c.2842G>T p.V948F (on ENST00000357337; = p.V986F on NM_015057.5) | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2
- MYO15A | c.5369C>T p.P1790L | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- MYO5A | c.4849T>G p.L1617V | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2
- NELL1 | c.1384T>G p.C462G | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NLRP2 | c.2946G>T p.Q982H | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- NLRX1 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NSUN2 | c.1917A>T p.R639S | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- NXF3 | c.569T>A p.I190K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.065); called by muse, mutect2
- OR11A1 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR2L13 | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PCDHA1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- PCDHB7 | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2
- PLCG2 | c.3755-2A>C p.X1252_splice | Splice Site (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- PNPLA6 | c.3543G>A p.W1181* (on ENST00000414982 / NM_001166111.2; = p.W1133* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- PTK2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RFX6 | c.380+1G>T p.X127_splice | Splice Site (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- RIPPLY2 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- RYR3 | c.3299G>T p.R1100L | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SDR42E2 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SFT2D2 | c.27C>G p.S9R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SHROOM2 | c.2383G>T p.A795S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2
- SLC25A1 | c.203-2A>C p.X68_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- SLC35F4 | c.96C>A p.S32R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, mutect2
- SLC5A6 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC66A2 | c.262A>T p.M88L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- SPRY3 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ST14 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by mutect2, varscan2
- TBC1D4 | c.2650G>T p.A884S | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- THSD7B | c.4422G>T p.Q1474H (on ENST00000272643; = p.Q1472H on NM_001316349.2) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2
- TRAF5 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2
- TRHDE | c.3026T>A p.L1009H | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2
- TSR2 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.594); called by muse, mutect2
- TTN | c.36993G>C p.E12331D (on ENST00000591111; = p.E4907D on NM_003319.4) | Missense Mutation (SNP) | VAF 15/176 reads (9%) | PolyPhen benign (0.21); called by muse, mutect2
- WASL | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WHAMM | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- XIRP2 | c.7912G>C p.G2638R (on ENST00000628543; = p.G2813R on NM_152381.6) | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2
- ZDHHC23 | c.1060T>A p.C354S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); called by muse, varscan2
- ZNF292 | c.5579G>A p.C1860Y | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ACAN | c.5676G>A p.P1892= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs772667742; called by muse, mutect2, varscan2
- ANK3 | c.1332G>C p.G444= | Silent (SNP) | VAF 10/175 reads (6%) | called by muse, mutect2
- BCOR | c.1704C>G p.A568= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- CACNA1F | c.5844C>T p.T1948= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- CAMTA1 | c.1842G>C p.P614= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- CEP126 | c.2109A>G p.G703= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, varscan2
- CFAP47 | c.2581C>A p.R861= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV52884313; called by muse, mutect2
- CLRN1 | c.645T>C p.F215= | Silent (SNP) | VAF 30/444 reads (7%) | called by muse, mutect2
- DMD | c.5760G>A p.Q1920= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- EMSY | c.1887C>T p.P629= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as rs1168661404; called by muse, mutect2
- FERD3L | c.300C>T p.Y100= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as rs1410313015, COSV51762957; called by muse, mutect2
- FOXRED1 | c.450G>T p.L150= | Silent (SNP) | VAF 17/237 reads (7%) | called by muse, mutect2
- GFPT1 | c.993C>T p.L331= (on ENST00000357308 / NM_001244710.2; = p.L313= on NM_002056.4) | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- GLRA4 | c.465C>T p.F155= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV65456238; called by muse, mutect2
- HTR3A | c.1251G>C p.G417= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- JAG2 | c.3249G>A p.L1083= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV59309740; called by muse, mutect2
- LEF1 | c.744C>T p.P248= | Silent (SNP) | VAF 16/224 reads (7%) | catalogued as rs151297517; called by muse, mutect2
- MGAT1 | c.78C>G p.L26= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2
- MTNR1B | c.865C>T p.L289= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- OR4K14 | c.513C>T p.G171= | Silent (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- OR52E2 | c.318C>A p.I106= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV58611887; called by muse, mutect2
- OR6B1 | c.36C>T p.F12= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- PC | c.1854C>T p.F618= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV67371301; called by muse, mutect2
- PDE8B | c.1647A>G p.Q549= | Silent (SNP) | VAF 10/173 reads (6%) | catalogued as rs1395910907; called by muse, mutect2
- PLEKHB2 | c.399G>T p.T133= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as COSV52175531; called by muse, mutect2
- SLC22A6 | c.459C>A p.G153= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV64560923; called by muse, mutect2, varscan2
- TTN | c.100323G>C p.V33441= (on ENST00000591111; = p.V26017= on NM_003319.4) | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- UNC79 | c.561A>G p.P187= (on ENST00000393151 / NM_001346218.2; = p.P10= on NM_020818.5) | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as rs1190183048; called by muse, mutect2
- VCAN | c.690T>C p.Y230= | Silent (SNP) | VAF 55/506 reads (11%) | catalogued as rs539798172; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ZEB1 | c.1737T>C p.D579= | Silent (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- AF121898.1 | n.205+24554A>C | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- AL353804.4 | chrX:73825908 A>G | 5'Flank (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- CHTF8 | chr16:69132500 del CGAGCGCG | 5'Flank (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- CMTM5 | c.-21G>T | 5'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- CRB1 | c.2677-441dup | Intron (INS) | VAF 15/135 reads (11%) | called by mutect2, pindel, varscan2
- CRYGS | c.22-50A>G | Intron (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- MGAM | c.4619-11220A>T | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- MRNIP | chr5:179860663 C>G | 5'Flank (SNP) | VAF 33/302 reads (11%) | called by muse, mutect2, varscan2
- MS4A6A | c.-194A>G | 5'UTR (SNP) | VAF 12/165 reads (7%) | called by muse, mutect2
- NAP1L1 | c.207-784G>T | Intron (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- NCKAP1L | c.1339-26G>T | Intron (SNP) | VAF 17/275 reads (6%) | called by muse, mutect2
- NDUFA3 | c.86-259C>G | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- OR2W5 | n.1052G>C | RNA (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- PCDHB6 | chr5:141157608 G>T | 3'Flank (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- PEX10 | c.-21G>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- PPP1R14D | c.256-1014C>T | Intron (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- PQBP1 | c.179+273G>C | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- RGS2 | c.441+11A>T | Intron (SNP) | VAF 28/504 reads (6%) | catalogued as COSV99343284; called by muse, mutect2
- SORBS2 | c.-197-5973C>T | Intron (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- UPRT | c.387-2035G>T | Intron (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- WDR59 | c.1713-15C>T | Intron (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2
- XIRP2 | c.*416T>A | 3'UTR (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
